Gene-level copy-number profile of tumor specimen C3L-02463-01 (profiled together with C3L-02463-02) from CPTAC case C3L-02463, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 63.8 years (23,313 days).
Specimen C3L-02463-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e0186e32-8216-4a42-99bf-c34a3a2c15bb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02463-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/f504c8f2-2021-4e2f-be75-c7516b1e52de

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6,221; copy number 1: 4,981; copy number 2: 47,139; copy number 3: 458; copy number 4: 90; copy number 5: 19; copy number 6: 2.

Caution: 6,203 autosomal genes are at 0 copies in this file, far more than a typical tumor; the lists below are given as recorded.

Homozygous deletions (total copy number 0; autosomes only): 6,203 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:152,308,283–152,918,463, 15 genes (within-gene range 0–2): AC080078.1, AC080078.2, FBXW7, FBXW7-AS1, AC023424.2, MIR3140, MIR4453HG, MIR4453, RPS3AP18, AC023424.1, TMEM154, AC106882.1, TIGD4, ARFIP1, NSA2P6.
- chr6:105,919–19,321,021, 321 genes (broad region; genes not listed).
- chr6:19,348,181–19,349,076, 1 gene: RPL5P20.
- chr6:104,831,129–105,180,014, 8 genes (within-gene range 0–1): AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3.
- chr6:165,327,287–170,738,536, 117 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:12,134–138,253,217, 2,253 genes (broad region; genes not listed).
- chr12:75,563,202–76,559,809, 22 genes: AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6, RN7SL734P, AC011611.2, AC011611.1, PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5, AC233290.2, AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8.
- chr12:114,238,970–133,238,549, 526 genes (broad region; genes not listed).
- chr17:142,789–12,768,949, 500 genes (within-gene range 0–2) (broad region; genes not listed).
- chr17:13,755,574–17,610,485, 142 genes (broad region; genes not listed).
- chr17:17,776,686–20,009,234, 139 genes (within-gene range 0–2) (broad region; genes not listed).
- chr17:29,390,363–29,551,903, 1 gene (within-gene range 0–1): TAOK1.
- chr17:29,424,762–29,445,400, 2 genes: RNU6-711P, RNU6-1034P.
- chr17:35,092,208–36,936,670, 104 genes (within-gene range 0–2) (broad region; genes not listed).
- chr17:41,848,518–41,930,542, 3 genes (within-gene range 0–2): KLHL11, ACLY, AC125257.2.
- chr17:50,847,950–83,240,804, 930 genes (broad region; genes not listed).
- chr18:45,034–14,499,278, 340 genes (broad region; genes not listed).
- chr18:23,453,287–80,247,514, 779 genes (within-gene range 0–4) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 20 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:14,728,272–15,330,282, 20 genes, copy number 5–6: ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005901.2, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.

Autosomal genes at a single copy (total copy number 1): 2,145. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
